Somatic mutation profile of tumor specimen TCGA-98-8021-01A (aliquot TCGA-98-8021-01A-11D-2244-08) from TCGA case TCGA-98-8021, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 75.9 years (27,738 days).
Specimen TCGA-98-8021-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 642712c9-463c-4cae-9874-8f68aa0fff15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-98-8021-10A (Blood Derived Normal), aliquot TCGA-98-8021-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acc7e316-3046-4e8d-8eae-e401df7f2c7f

The open-access MAF lists 1,075 somatic variants for this specimen: 798 protein-altering or splice-affecting, 264 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 708, Silent 264, Nonsense Mutation 60, Splice Site 13, Splice Region 7, Intron 7, Frame Shift Del 7, Translation Start Site 3, 5'UTR 2, 3'UTR 2, 3'Flank 1, RNA 1.

Variants (750 of 1,075; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A5 | c.3206G>T p.G1069V | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs281874712, CM107309, CM145029, COSV100088792; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- INSR | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 9/70 reads (13%) | catalogued as rs121913151, CM920378, COSV57164886; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.1940del p.P647Hfs*283 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | catalogued as rs770315135, CM119945, COSV56413885, COSV99040251; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- A1CF | c.561G>C p.E187D | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV99257632; called by muse, mutect2, varscan2
- A2M | c.2284A>G p.I762V | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100589000; called by muse, mutect2, varscan2
- ABCA12 | c.2791C>G p.Q931E (on ENST00000272895 / NM_173076.3; = p.Q613E on NM_015657.3) | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV99791858; called by muse, mutect2, varscan2
- ABCA12 | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.883); catalogued as COSV55954325, COSV99788064, COSV99791861; called by muse, mutect2, varscan2
- ABCB7 | c.945-1G>A p.X315_splice (on ENST00000373394 / NM_001271696.3; = p.X316_splice on NM_004299.6) | Splice Site (SNP) | VAF 7/53 reads (13%) | catalogued as COSV99504801, COSV99504818; called by muse, mutect2, varscan2
- ABCC10 | c.2898C>G p.F966L (on ENST00000372530 / NM_001198934.2; = p.F938L on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV99767939; called by muse, mutect2, varscan2
- ABCC11 | c.3980G>T p.C1327F | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62321985; called by muse, mutect2, varscan2
- ABCD3 | c.1235C>T p.S412L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV100931461; called by muse, mutect2, varscan2
- ABRAXAS2 | c.45C>G p.F15L | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV100045114, COSV53717570; called by muse, mutect2
- ACSF3 | c.857G>T p.R286L | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV100441565; called by muse, mutect2, varscan2
- ACTN1 | c.1955A>T p.E652V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as COSV99518504; called by muse, mutect2, varscan2
- ADAD1 | c.624G>C p.K208N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as COSV56641390, COSV99635265, COSV99636245; called by muse, mutect2, varscan2
- ADAMTS7 | c.3683G>A p.G1228E | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.015); catalogued as rs1257213051, COSV101183243; called by muse, mutect2
- AFG3L2 | c.1819C>T p.Q607* | Nonsense Mutation (SNP) | VAF 24/140 reads (17%) | catalogued as COSV99302159; called by muse, mutect2, varscan2
- AGBL5 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.884); catalogued as COSV100549422; called by muse, mutect2
- AHCTF1 | c.2449G>C p.D817H (on ENST00000366508; = p.D791H on NM_015446.5) | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100404384; called by muse, mutect2
- AHCTF1 | c.1444G>A p.D482N (on ENST00000366508; = p.D456N on NM_015446.5) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100404387; called by muse, mutect2, varscan2
- AHI1 | c.818C>G p.S273C | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV99663659; called by muse, mutect2
- AHNAK2 | c.1868G>C p.R623T | Missense Mutation (SNP) | VAF 38/325 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.114); catalogued as COSV100318866; called by muse, mutect2, varscan2
- AKAP13 | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100774579; called by muse, mutect2, varscan2
- ALDOA | c.817G>C p.D273H (on ENST00000642816 / NM_001243177.4; = p.D219H on NM_184041.5) | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV100582230, COSV57634140; called by muse, mutect2, varscan2
- ALG8 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs1345095969, COSV100220276; called by muse, mutect2
- ALKBH1 | c.565T>G p.Y189D | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as COSV99380777; called by muse, mutect2, varscan2
- ALPK1 | c.3499G>C p.E1167Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV99455133; called by muse, mutect2, varscan2
- ANAPC7 | c.805G>C p.D269H | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV101484811; called by muse, mutect2, varscan2
- ANGPT1 | c.342G>C p.Q114H | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs200040737; called by muse, mutect2, varscan2
- ANKMY1 | c.139A>G p.S47G | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV99803158; called by muse, mutect2, varscan2
- ANKRD30A | c.1309A>T p.N437Y (on ENST00000611781; = p.N381Y on NM_052997.2) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV100654417; called by muse, mutect2
- ANKRD6 | c.1800G>C p.M600I (on ENST00000339746 / NM_001242809.2; = p.M595I on NM_014942.4) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100330327; called by muse, mutect2, varscan2
- ANO4 | c.968G>T p.C323F (on ENST00000392977 / NM_001286615.2; = p.C288F on NM_178826.4) | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.218); catalogued as COSV54600131; called by muse, mutect2, varscan2
- AP4M1 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as rs773269627, COSV100385147; ClinVar: uncertain significance; called by muse, varscan2
- APBB1IP | c.1341T>A p.N447K | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV100882253; called by muse, mutect2, varscan2
- APOBEC3D | c.1024A>G p.K342E | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs376325106; called by muse, mutect2, varscan2
- APOBEC3F | c.1053C>G p.F351L | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100415260; called by muse, mutect2, varscan2
- APOBEC3G | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.786); catalogued as COSV101349111; called by muse, mutect2, varscan2
- ARFGAP3 | c.1156G>C p.D386H | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99605545; called by muse, mutect2, varscan2
- ARHGAP21 | c.5755G>C p.D1919H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100256634; called by muse, mutect2, varscan2
- ARHGAP29 | c.3097G>C p.E1033Q | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99559001; called by muse, mutect2, varscan2
- ARHGAP31 | c.1675G>A p.D559N | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99957703; called by muse, mutect2, varscan2
- ARHGEF28 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.991); catalogued as rs371272526; called by muse, mutect2, varscan2
- ARID1B | c.1888-1G>T p.X630_splice | Splice Site (SNP) | VAF 7/48 reads (15%) | catalogued as COSV99271766; called by muse, mutect2, varscan2
- ARID2 | c.4477G>A p.V1493I | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as COSV57599059, COSV99044006; called by muse, mutect2, varscan2
- ARID5B | c.2413G>C p.E805Q | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as rs1316010573, COSV54428005, COSV99690400; called by muse, mutect2, varscan2
- ARMC5 | c.975G>T p.E325D | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.681); catalogued as COSV51659509; called by muse, mutect2, varscan2
- ARMCX2 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as rs781887055, COSV57529506; called by muse, mutect2, varscan2
- ASCC2 | c.30G>C p.Q10H | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.18); catalogued as rs373808774; called by muse, mutect2, varscan2
- ASXL3 | c.1963A>G p.S655G | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); catalogued as rs369321765; called by muse, varscan2
- ATM | c.6413G>C p.R2138T | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV99587583, COSV99591777; called by mutect2, varscan2
- ATP13A1 | c.3250C>A p.Q1084K | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99179571; called by muse, mutect2, varscan2
- ATP1A4 | c.756C>G p.F252L | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.24); catalogued as COSV100927640, COSV63625395; called by muse, mutect2
- ATP2C1 | c.1685C>G p.S562* | Nonsense Mutation (SNP) | VAF 11/113 reads (10%) | catalogued as CM003654, COSV100146987; called by muse, mutect2, varscan2
- ATP7B | c.3130C>G p.L1044V | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.066); catalogued as COSV99666934; called by muse, mutect2, varscan2
- ATP8B3 | c.1231C>T p.H411Y | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); catalogued as COSV100034936; called by muse, mutect2
- ATXN7L3 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV66989341, COSV66989680; called by muse, mutect2, varscan2
- BCAS3 | c.1951C>T p.R651* (on ENST00000390652 / NM_001353144.2; = p.R636* on NM_017679.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as rs769939544, COSV66780687; called by muse, mutect2, varscan2
- BCHE | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV100012969; called by muse, mutect2
- BCLAF3 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV100503395, COSV100503410; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2578G>A p.G860R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV100863931; called by muse, mutect2, varscan2
- BLK | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99034793, COSV99377599; called by muse, mutect2, varscan2
- BMPER | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV99780498; called by muse, mutect2, varscan2
- BRINP2 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV64178002; called by muse, mutect2, varscan2
- BTN3A3 | c.1633G>A p.G545R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99765035; called by muse, mutect2, varscan2
- C12orf4 | c.1646C>A p.T549K | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.852); catalogued as COSV99712926; called by muse, mutect2, varscan2
- C1orf116 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.283); catalogued as COSV100848018; called by muse, mutect2, varscan2
- C2CD3 | c.1174G>T p.D392Y | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100487378; called by muse, mutect2, varscan2
- C2CD5 | c.2954C>G p.P985R | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as COSV100449011; called by muse, mutect2, varscan2
- C2orf16 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.82); catalogued as COSV101284419; called by muse, mutect2
- C2orf16 | c.875G>T p.G292V | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.056); catalogued as COSV101284420; called by muse, mutect2
- C2orf16 | c.5653C>T p.H1885Y | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.6); catalogued as COSV100821004; called by muse, mutect2, varscan2
- C3orf20 | c.1749G>C p.K583N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV99514535; called by muse, mutect2, varscan2
- CABIN1 | c.2974G>C p.E992Q | Missense Mutation (SNP) | VAF 15/216 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99573969; called by muse, mutect2
- CABP4 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs139328894; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1A | c.3199G>C p.E1067Q | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV100803164; called by muse, mutect2, varscan2
- CACNA1F | c.1188G>C p.Q396H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100545352; called by muse, mutect2, varscan2
- CACTIN | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as COSV50267838; called by muse, mutect2, varscan2
- CACTIN | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV50271210, COSV99698859; called by muse, mutect2, varscan2
- CALHM5 | c.631C>G p.Q211E | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100635665; called by muse, mutect2, varscan2
- CAMK1 | c.1069G>C p.E357Q | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.431); catalogued as COSV56539747, COSV99844935; called by muse, mutect2, varscan2
- CAPN9 | c.1540G>A p.D514N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99681083; called by muse, mutect2, varscan2
- CARD14 | c.849G>C p.E283D | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as COSV100712618; called by muse, mutect2
- CARMIL3 | c.3169C>A p.H1057N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (1); PolyPhen possibly damaging (0.775); catalogued as COSV100549835; called by muse, mutect2, varscan2
- CARS1 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 78/364 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as rs762313201, COSV53457352; called by muse, mutect2, varscan2
- CASK | c.237G>C p.E79D | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.737); catalogued as COSV100587745; called by muse, mutect2, varscan2
- CAT | c.993G>C p.Q331H | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99573434; called by muse, mutect2, varscan2
- CBLL1 | c.687G>A p.M229I | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99755915; called by muse, mutect2, varscan2
- CCDC106 | c.186G>T p.K62N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV99553279; called by muse, mutect2, varscan2
- CCDC57 | c.1997G>C p.R666T | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100492656, COSV58934405; called by muse, mutect2, varscan2
- CCHCR1 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV100885756; called by muse, mutect2, varscan2
- CCNY | c.17C>G p.S6W | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99038003, COSV99591086; called by muse, mutect2, varscan2
- CD2BP2 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 73/295 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs765900907, COSV99977223; called by muse, mutect2, varscan2
- CD58 | c.320C>G p.S107W | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101043992, COSV65665227, COSV65665606; called by muse, mutect2
- CDH19 | c.140G>T p.W47L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100052280; called by muse, mutect2, varscan2
- CDH8 | c.2158G>C p.D720H | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100184024; called by muse, mutect2, varscan2
- CDK2 | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 12/343 reads (3%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.796); catalogued as COSV99906802; called by muse, mutect2
- CDK5RAP2 | c.1699C>G p.L567V | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100575728; called by muse, mutect2, varscan2
- CDNF | c.204C>G p.I68M | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.305); catalogued as COSV101012373, COSV101012383; called by muse, mutect2, varscan2
- CDR1 | c.687G>C p.K229N | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100983448; called by muse, mutect2, varscan2
- CEP170 | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100839864; called by muse, mutect2, varscan2
- CEP85L | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV100821404; called by muse, mutect2
- CERS5 | c.897G>C p.E299D | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as COSV100452076; called by muse, mutect2, varscan2
- CFAP100 | c.304C>A p.L102M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.141); catalogued as COSV100729413; called by mutect2, varscan2
- CFAP36 | c.396T>C p.N132= | Splice Region (SNP) | VAF 14/23 reads (61%) | catalogued as COSV100171149; called by muse, mutect2, varscan2
- CFP | c.901A>T p.T301S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as COSV99901661; called by muse, mutect2, varscan2
- CHD6 | c.2716C>T p.R906C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777147193, COSV58563657; called by muse, mutect2, varscan2
- CHD7 | c.35A>T p.E12V | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); catalogued as COSV101418427; called by muse, mutect2, varscan2
- CHMP7 | c.1121A>T p.D374V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV100500756; called by muse, mutect2, varscan2
- CHRD | c.1378C>T p.Q460* | Nonsense Mutation (SNP) | VAF 16/209 reads (8%) | catalogued as COSV99200762; called by muse, mutect2
- CHRNA1 | c.830T>A p.V277E (on ENST00000261007 / NM_001039523.3; = p.V252E on NM_000079.4) | Missense Mutation (SNP) | VAF 54/191 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99650705; called by muse, mutect2, varscan2
- CIB3 | c.86G>A p.R29K | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV99521913; called by muse, mutect2, varscan2
- CIC | c.3173C>G p.S1058* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV50561662; called by muse, mutect2, varscan2
- CIDEA | c.571C>G p.L191V | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100255365; called by muse, mutect2, varscan2
- CIP2A | c.645G>C p.L215F | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99843146; called by muse, mutect2
- CLEC16A | c.2796G>C p.Q932H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99901732; called by muse, varscan2
- CLHC1 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV100811498; called by muse, mutect2, varscan2
- CLIC6 | c.2109G>A p.M703I (on ENST00000360731 / NM_001317009.2; = p.M685I on NM_053277.3) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs1405536479, COSV62447384, COSV62449978; called by muse, mutect2
- CLSTN3 | c.2255G>T p.S752I | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as COSV99867660; called by muse, mutect2, varscan2
- CNDP1 | c.365C>A p.P122H | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100722527; called by muse, mutect2, varscan2
- CNOT3 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV99652316; called by muse, mutect2, varscan2
- CNTN4 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1199542195, COSV68561856; called by muse, mutect2, varscan2
- CNTN5 | c.2728G>C p.E910Q | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99681065; called by muse, mutect2, varscan2
- CNTNAP2 | c.972G>T p.K324N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.679); catalogued as COSV100672003; called by muse, mutect2, varscan2
- CNTRL | c.2125G>C p.E709Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as COSV99443781; called by muse, mutect2, varscan2
- COA8 | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99915029; called by muse, mutect2
- COL12A1 | c.7214A>T p.K2405M | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.404); catalogued as rs1451396376, COSV100486452; called by muse, mutect2
- COL13A1 | c.280C>G p.Q94E | Missense Mutation (SNP) | VAF 15/179 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.188); catalogued as COSV62567160; called by muse, mutect2
- COL20A1 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV100490488; called by muse, mutect2, varscan2
- COL22A1 | c.221G>T p.R74L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.282); catalogued as rs560673312, COSV100280668, COSV57351946; called by muse, varscan2
- COLGALT2 | c.857G>T p.R286I | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.522); catalogued as COSV100730859; called by muse, mutect2
- CPED1 | c.2524T>A p.L842M | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1165827920, COSV100121452; called by muse, mutect2, varscan2
- CPT1C | c.518G>T p.R173L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs1193860630, COSV54917313; called by muse, mutect2, varscan2
- CREBBP | c.5296G>A p.E1766K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99271868; called by muse, mutect2
- CRYBG2 | c.3859G>T p.E1287* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100366975; called by muse, mutect2
- CSTF2 | c.565-1G>C p.X189_splice | Splice Site (SNP) | VAF 24/118 reads (20%) | catalogued as COSV100802969, COSV63376172; called by muse, mutect2, varscan2
- CTNNA1 | c.1400C>A p.A467D | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100243236; called by muse, mutect2, varscan2
- CTTNBP2 | c.2380G>C p.E794Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.136); catalogued as COSV99354807; called by muse, mutect2, varscan2
- CUBN | c.1619C>T p.S540F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV100913487; called by muse, mutect2, varscan2
- CUBN | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100910653; called by muse, mutect2, varscan2
- CYP2A7 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.233); catalogued as COSV99394496; called by muse, mutect2, varscan2
- DCAF1 | c.625C>G p.L209V | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.969); catalogued as COSV100244933; called by muse, mutect2, varscan2
- DCAF12L1 | c.779C>A p.P260H | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV100948074, COSV100948439; called by muse, mutect2, varscan2
- DDIAS | c.1006G>C p.D336H | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); catalogued as COSV100231107, COSV100231348, COSV100231434; called by muse, mutect2, varscan2
- DDX10 | c.2245C>T p.R749W | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs763915011, COSV100489917; called by muse, varscan2
- DENND1A | c.1687G>A p.D563N | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1243663517, COSV65354952; called by muse, varscan2
- DENND4C | c.4537G>A p.E1513K (on ENST00000434457 / NM_001330640.2; = p.E1464K on NM_017925.7) | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.89); catalogued as COSV100727595; called by muse, mutect2, varscan2
- DEPDC1B | c.495G>C p.E165D | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV99409852; called by muse, mutect2, varscan2
- DHX15 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs777394319, COSV100391728; called by muse, varscan2
- DHX37 | c.1192-1G>C p.X398_splice | Splice Site (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100439484; called by mutect2, varscan2
- DHX57 | c.1577G>C p.R526P | Missense Mutation (SNP) | VAF 54/353 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.211); catalogued as COSV54882914, COSV54889599; called by muse, mutect2, varscan2
- DIS3L | c.1089G>C p.Q363H (on ENST00000319212 / NM_001143688.3; = p.Q280H on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.235); catalogued as COSV100055586; called by muse, mutect2, varscan2
- DMD | c.7634A>T p.E2545V | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV100629187; called by muse, mutect2, varscan2
- DMD | c.6229G>A p.A2077T | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.028); catalogued as COSV100822555; called by muse, mutect2, varscan2
- DMRTA1 | c.1022G>T p.R341M | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV57925539; called by muse, mutect2, varscan2
- DMWD | c.799G>C p.A267P | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV99353655; called by muse, mutect2, varscan2
- DMXL1 | c.3529G>T p.G1177C | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100224925; called by muse, mutect2, varscan2
- DNAH11 | c.6154C>G p.L2052V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100180720; called by muse, mutect2, varscan2
- DNAH2 | c.4618G>A p.D1540N | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101209580; called by muse, mutect2, varscan2
- DNAH7 | c.9460G>T p.V3154F | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100417439; called by mutect2, varscan2
- DNAH7 | c.7901C>T p.S2634F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56766389, COSV56774021; called by muse, mutect2, varscan2
- DNAH8 | c.7195G>T p.V2399F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV100547173; called by muse, mutect2, varscan2
- DNAH9 | c.2504C>A p.S835Y | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as COSV52339496, COSV52360552; called by muse, mutect2, varscan2
- DNAJB11 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.895); catalogued as rs1446240668, COSV54003517; called by muse, mutect2, varscan2
- DNHD1 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 58/318 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV99600932; called by muse, varscan2
- DOCK10 | c.3206G>T p.R1069L | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99287542, COSV99291510; called by muse, mutect2, varscan2
- DOCK4 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.562); catalogued as COSV101455743; called by muse, mutect2, varscan2
- DPY30 | c.175C>G p.Q59E | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV99705097; called by muse, mutect2
- DPYD | c.871G>C p.D291H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.264); catalogued as COSV100929374, COSV64599655; called by muse, mutect2, varscan2
- DSG1 | c.335C>T p.T112I | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1448481228, COSV99936544; called by muse, mutect2, varscan2
- DSP | c.919C>G p.Q307E | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs1238227166, COSV101131734; called by muse, mutect2, varscan2
- DYM | c.272C>A p.S91* | Nonsense Mutation (SNP) | VAF 8/90 reads (9%) | catalogued as COSV99494135; called by muse, mutect2
- DYSF | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1333857093, COSV99250276; called by muse, mutect2, varscan2
- E2F7 | c.669G>C p.Q223H | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV100523931; called by muse, mutect2, varscan2
- E2F8 | c.2108C>T p.S703L | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100001714; called by muse, mutect2, varscan2
- EDC4 | c.2722G>C p.D908H | Missense Mutation (SNP) | VAF 16/195 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100197779; called by muse, mutect2
- EDDM3B | c.262C>A p.R88S | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100460906, COSV58747008; called by muse, mutect2, varscan2
- EFCAB14 | c.958G>C p.E320Q | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.626); catalogued as COSV100905664; called by muse, mutect2
- EFCAB6 | c.553G>T p.D185Y | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99414370; called by muse, mutect2
- EGFLAM | c.291G>A p.T97= | Splice Region (SNP) | VAF 14/50 reads (28%) | catalogued as rs1222340406, COSV100473382; called by muse, mutect2, varscan2
- EIF2AK3 | c.3290C>G p.S1097* | Nonsense Mutation (SNP) | VAF 29/175 reads (17%) | catalogued as COSV100304108; called by muse, mutect2, varscan2
- ELP2 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.282); catalogued as COSV100627070; called by muse, mutect2
- ELP3 | c.744G>C p.Q248H | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99834199; called by muse, mutect2
- ELP4 | c.539G>T p.R180I (on ENST00000350638; = p.R179I on NM_019040.5) | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as COSV100635872, COSV63350474; called by muse, mutect2, varscan2
- EPHA1 | c.2848G>A p.A950T | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0.012); catalogued as rs762781363, COSV51968574; called by muse, mutect2, varscan2
- EPS8L3 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV62608695; called by muse, mutect2, varscan2
- ERICH3 | c.1798G>T p.V600L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV100445660; called by muse, mutect2, varscan2
- ESR1 | c.1609T>C p.Y537H | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52784978, COSV52804811, COSV99237981; called by muse, mutect2, varscan2
- EYA1 | c.1295G>C p.R432T | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV100380241; called by muse, mutect2, varscan2
- EYA4 | c.1270G>A p.D424N (on ENST00000531901 / NM_001301013.1; = p.D418N on NM_004100.5) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV62060153; called by muse, mutect2, varscan2
- FADS1 | c.1077C>G p.F359L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV100650308; called by muse, mutect2, varscan2
- FAH | c.642G>T p.E214D | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1347205703, COSV99930541; called by muse, mutect2, varscan2
- FAM111A | c.1727C>G p.S576C | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100659447; called by muse, mutect2, varscan2
- FAM135B | c.1093C>G p.Q365E | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99427310; called by muse, mutect2, varscan2
- FAM186B | c.1598G>C p.R533T | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.112); catalogued as COSV99220232; called by muse, mutect2, varscan2
- FAM90A1 | c.1159G>C p.D387H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.984); catalogued as rs776504177, COSV100274492, COSV100274512; called by muse, mutect2, varscan2
- FAM9C | c.462G>C p.K154N | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100452889, COSV61775758; called by muse, mutect2, varscan2
- FARSA | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1189769005, COSV58903969, COSV58905018; called by muse, mutect2, varscan2
- FASTKD2 | c.521C>G p.S174* | Nonsense Mutation (SNP) | VAF 13/96 reads (14%) | catalogued as COSV99379236; called by muse, mutect2, varscan2
- FASTKD2 | c.980G>T p.R327M | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV99379238; called by muse, mutect2, varscan2
- FAT1 | c.7417A>T p.R2473* | Nonsense Mutation (SNP) | VAF 32/141 reads (23%) | catalogued as COSV101499634; called by muse, mutect2, varscan2
- FBXL7 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV61653745; called by muse, mutect2
- FCAMR | c.218G>A p.W73* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100249738; called by muse, mutect2, varscan2
- FCGR3A | c.574C>G p.Q192E | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV100914711; called by muse, mutect2
- FCGR3B | c.574C>G p.Q192E | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99670756; called by muse, mutect2
- FCHO1 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV99406459; called by muse, mutect2, varscan2
- FER1L6 | c.1821G>A p.L607= | Splice Region (SNP) | VAF 47/269 reads (17%) | catalogued as COSV101205922, COSV101206172; called by muse, mutect2, varscan2
- FEZF2 | c.1069G>C p.G357R | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99334996; called by muse, mutect2, varscan2
- FFAR2 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140779660; called by muse, varscan2
- FFAR2 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs142684334, COSV99876172; called by muse, varscan2
- FGFR1 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.816); catalogued as rs778531708, COSV58331058; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FILIP1 | c.352G>C p.A118P | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV99386080; called by muse, mutect2
- FKBPL | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV64322562; called by muse, mutect2
- FLG | c.9974C>G p.S3325C | Missense Mutation (SNP) | VAF 150/818 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100912127; called by muse, mutect2, varscan2
- FLG | c.9683C>G p.S3228C | Missense Mutation (SNP) | VAF 49/272 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100912128; called by muse, mutect2, varscan2
- FMNL3 | c.1522C>G p.P508A | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV53301974, COSV99526941; called by muse, mutect2, varscan2
- FMOD | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as COSV100724628; called by muse, mutect2, varscan2
- FNIP1 | c.2684C>T p.S895L | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as COSV100330593; called by muse, mutect2
- FOXB1 | c.184C>A p.R62S | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101249926; called by muse, mutect2, varscan2
- FOXK1 | c.1197G>C p.Q399H | Missense Mutation (SNP) | VAF 11/185 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV100195782; called by muse, mutect2
- FPGT-TNNI3K | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100599429; called by muse, mutect2, varscan2
- FXR1 | c.1154G>A p.G385E | Missense Mutation (SNP) | VAF 11/209 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV99976663; called by muse, mutect2
- GABRA6 | c.1178G>C p.R393T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99195059; called by muse, mutect2, varscan2
- GAGE10 | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101340052; called by muse, mutect2, varscan2
- GAGE10 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV101340053; called by muse, mutect2, varscan2
- GALNT13 | c.1197A>T p.K399N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.127); catalogued as COSV101224176; called by muse, mutect2, varscan2
- GATA4 | c.741G>A p.M247I | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as COSV100633025; called by muse, mutect2, varscan2
- GCA | c.193G>C p.D65H | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99280676; called by muse, mutect2, varscan2
- GCC2 | c.3040C>G p.Q1014E | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs1333097633, COSV100565639; called by muse, mutect2, varscan2
- GCFC2 | c.722G>A p.R241K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.039); catalogued as COSV100319719; called by muse, mutect2, varscan2
- GDPD1 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.035); catalogued as COSV52385482; called by muse, mutect2, varscan2
- GDPD4 | c.643A>G p.M215V | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1342875100, COSV100265601; called by muse, mutect2, varscan2
- GEMIN5 | c.3689C>T p.A1230V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as rs1410641008, COSV99594237; called by muse, mutect2, varscan2
- GHDC | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs772564297, COSV100054947; called by muse, mutect2, varscan2
- GHR | c.958G>C p.E320Q | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100051957; called by muse, mutect2, varscan2
- GIGYF1 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.778); catalogued as COSV99309972; called by muse, mutect2, varscan2
- GIGYF2 | c.772G>C p.D258H | Missense Mutation (SNP) | VAF 28/305 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as COSV101004596; called by muse, mutect2
- GINS3 | c.527T>A p.F176Y | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.781); catalogued as COSV100139400; called by muse, mutect2
- GIPC2 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100883335; called by muse, mutect2, varscan2
- GIPC3 | c.320G>C p.R107P | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100461513; called by muse, mutect2, varscan2
- GJA8 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.993); catalogued as CD163653, COSV53788600, COSV53789126, COSV99569681; called by muse, mutect2, varscan2
- GJC3 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as COSV100458520; called by muse, mutect2, varscan2
- GK5 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101242338, COSV67485402; called by muse, mutect2
- GLI1 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.62); catalogued as COSV57361397, COSV57364216; called by muse, mutect2
- GLUD2 | c.1604G>A p.R535K | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100047087; called by muse, mutect2, varscan2
- GLYATL1 | c.162G>T p.M54I (on ENST00000317391 / NM_001354699.1; = p.M85I on NM_080661.4) | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.102); catalogued as COSV100265552; called by muse, mutect2, varscan2
- GNB5 | c.715G>A p.D239N (on ENST00000261837 / NM_016194.4; = p.D197N on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV99953636; called by muse, mutect2, varscan2
- GPATCH1 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV99404326; called by muse, varscan2
- GPCPD1 | c.895C>A p.P299T | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV100980250; called by muse, mutect2, varscan2
- GPI | c.1000G>C p.E334Q | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.654); catalogued as COSV100731573; called by muse, mutect2, varscan2
- GPR139 | c.785T>A p.L262Q | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.588); catalogued as COSV100430030; called by muse, mutect2, varscan2
- GPR20 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.691); catalogued as rs371640941; called by muse, mutect2, varscan2
- GPR21 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.824); catalogued as rs142528272; called by muse, mutect2, varscan2
- GPRIN3 | c.361C>G p.L121V | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.107); catalogued as COSV100310995, COSV60886595; called by muse, mutect2, varscan2
- GPT | c.239C>G p.T80S | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.152); catalogued as COSV99477824; called by muse, mutect2, varscan2
- GPX6 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs1415715141, COSV100724908; called by muse, mutect2, varscan2
- GRAMD1C | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV100822996; called by muse, mutect2, varscan2
- GRIA1 | c.869C>G p.S290C | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as COSV99602224; called by muse, mutect2, varscan2
- GRIK1 | c.600C>G p.I200M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.77); catalogued as COSV100517864, COSV58720206; called by muse, mutect2, varscan2
- GRIK3 | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 16/218 reads (7%) | catalogued as COSV66144907; called by muse, mutect2
- GRIK4 | c.2296G>T p.A766S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99074513; called by muse, mutect2, varscan2
- GRIK5 | c.1587+1G>T p.X529_splice | Splice Site (SNP) | VAF 5/30 reads (17%) | catalogued as COSV99491341; called by muse, mutect2, varscan2
- GRIN2A | c.583T>A p.F195I | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100410978; called by muse, mutect2, varscan2
- GRM8 | c.1225G>T p.V409L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100285844; called by muse, mutect2, varscan2
- GRM8 | c.120A>G p.I40M | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV100285846, COSV58816215; called by muse, mutect2, varscan2
- GUCA1C | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.826); catalogued as COSV53756034, COSV53756094, COSV99659956; called by muse, mutect2, varscan2
- GYS2 | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.392); catalogued as rs893029436, COSV99680237; called by muse, mutect2, varscan2
- H1-2 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.883); catalogued as rs1252419231, COSV59189887, COSV59190473; called by muse, mutect2, varscan2
- HACE1 | c.1672C>T p.H558Y | Missense Mutation (SNP) | VAF 36/252 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV99494248; called by muse, mutect2, varscan2
- HCN1 | c.1551C>A p.H517Q | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV100302170, COSV57494940; called by muse, mutect2, varscan2
- HECTD1 | c.2120C>T p.S707L | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101237507; called by muse, mutect2
- HEMGN | c.1018C>T p.H340Y | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.93); PolyPhen benign (0.031); catalogued as COSV52325102; called by muse, mutect2
- HEPHL1 | c.2613A>T p.R871S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.679); catalogued as COSV100244387; called by muse, mutect2, varscan2
- HFM1 | c.946G>T p.A316S | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99646757; called by muse, mutect2, varscan2
- HGF | c.1964C>G p.S655C | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99738416; called by muse, mutect2, varscan2
- HIF1A | c.2246C>G p.S749* | Nonsense Mutation (SNP) | VAF 13/95 reads (14%) | catalogued as COSV100049236; called by muse, mutect2, varscan2
- HINT1 | c.93C>G p.I31M | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as rs749444327, COSV100401208; called by muse, mutect2
- HIRIP3 | c.1544G>C p.G515A | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as COSV99663317; called by muse, mutect2, varscan2
- HIVEP1 | c.4223C>A p.S1408Y | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.273); catalogued as COSV101045704; called by muse, mutect2, varscan2
- HIVEP2 | c.4749G>C p.Q1583H | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV99175341; called by muse, mutect2, varscan2
- HIVEP2 | c.3580G>C p.E1194Q | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.143); catalogued as COSV50014055; called by muse, mutect2, varscan2
- HMMR | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as COSV100701048; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.274G>C p.E92Q (on ENST00000354667 / NM_031243.3; = p.E80Q on NM_002137.4) | Missense Mutation (SNP) | VAF 40/238 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as COSV61161020; called by muse, mutect2, varscan2
- HPS1 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); catalogued as rs199755594, COSV100282803; called by muse, mutect2, varscan2
- HRH4 | c.134A>C p.N45T | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.098); catalogued as COSV99908017; called by muse, mutect2, varscan2
- HSD17B12 | c.393G>A p.V131= | Splice Region (SNP) | VAF 23/113 reads (20%) | catalogued as COSV99551070; called by muse, mutect2, varscan2
- HTR1E | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 21/151 reads (14%) | catalogued as COSV100541290; called by muse, mutect2, varscan2
- HTR3E | c.306G>T p.W102C (on ENST00000415389 / NM_001256613.1; = p.W117C on NM_182589.2) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100094478; called by muse, mutect2, varscan2
- IFT122 | c.2575G>A p.E859K (on ENST00000348417 / NM_052989.3; = p.E800K on NM_018262.4) | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.192); catalogued as COSV56206042; called by muse, mutect2
- IGF2BP3 | c.1381G>C p.E461Q | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs775406714, COSV51682519, COSV99325595, COSV99325815; called by muse, mutect2, varscan2
- IGSF3 | c.259C>A p.R87S | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100605073; called by muse, mutect2
- IKBKB | c.2112G>C p.K704N | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100645818; called by muse, mutect2
- IL21R | c.1472A>G p.D491G | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100560533; called by muse, mutect2, varscan2
- INSYN2A | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 17/185 reads (9%) | catalogued as COSV99732466; called by muse, mutect2
- INTS7 | c.2272G>A p.E758K | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.084); catalogued as COSV100877569; called by muse, mutect2
- IPCEF1 | c.950A>T p.Y317F | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99500454; called by muse, mutect2, varscan2
- IPO8 | c.2256G>T p.R752S | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.719); catalogued as COSV99805637; called by muse, mutect2, varscan2
- IQSEC2 | c.3445G>A p.D1149N (on ENST00000642864 / NM_001111125.3; = p.D944N on NM_015075.2) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV100945089; called by muse, mutect2, varscan2
- IRF2BPL | c.2185C>T p.Q729* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | catalogued as COSV99468463; called by muse, mutect2
- IRF4 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101110947; called by muse, mutect2, varscan2
- IRS4 | c.2246G>A p.R749K | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.145); catalogued as rs774511400, COSV100929717; called by muse, mutect2, varscan2
- IRX2 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as COSV100121825, COSV57409564; called by muse, mutect2, varscan2
- ITGA6 | c.1484C>T p.S495L (on ENST00000442250; = p.S456L on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99906065; called by muse, mutect2, varscan2
- ITGAD | c.2321G>C p.C774S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101210573, COSV66758356; called by muse, varscan2
- ITGB3BP | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.203); catalogued as COSV99371036, COSV99371308; called by muse, mutect2, varscan2
- ITPR2 | c.6885G>T p.M2295I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1442227241, COSV101190150; called by muse, mutect2, varscan2
- ITPR2 | c.4057C>T p.P1353S | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.034); catalogued as COSV101190151; called by muse, mutect2
- ITSN2 | c.2510C>T p.S837F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV100744137; called by muse, mutect2, varscan2
- ITSN2 | c.1891C>T p.Q631* | Nonsense Mutation (SNP) | VAF 6/92 reads (7%) | catalogued as COSV100744138; called by muse, mutect2
- IZUMO4 | c.536+1G>A p.X179_splice | Splice Site (SNP) | VAF 73/219 reads (33%) | catalogued as rs756955222, COSV100643023; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1417G>T p.E473* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100584200, COSV59825960; called by muse, mutect2, varscan2
- KCNA4 | c.1034G>T p.G345V | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100068481, COSV60250841; called by muse, mutect2, varscan2
- KCNA7 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as rs762119570, COSV55503557; called by muse, mutect2, varscan2
- KCNA7 | c.1249G>T p.D417Y | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.131); catalogued as COSV99672024; called by muse, mutect2
- KCNC2 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.742); catalogued as COSV100129818, COSV54373751; called by muse, mutect2, varscan2
- KCNH3 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.082); catalogued as COSV99235760; called by muse, mutect2, varscan2
- KCNIP4 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.81); catalogued as COSV99764364; called by muse, mutect2, varscan2
- KCNMB4 | c.362G>C p.R121T | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99253416; called by muse, mutect2, varscan2
- KCNQ2 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV100610536; called by muse, mutect2, varscan2
- KDM1A | c.1571G>C p.R524T | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV100752822, COSV63086823; called by muse, mutect2, varscan2
- KDM4A | c.2647C>T p.R883W | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1425619898, COSV100969647; called by muse, mutect2
- KIAA0930 | c.229G>C p.E77Q (on ENST00000336156 / NM_001009880.2; = p.E82Q on NM_015264.2) | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99326044; called by muse, mutect2, varscan2
- KIAA1958 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100516445; called by muse, mutect2, varscan2
- KIF21B | c.3526G>C p.E1176Q | Missense Mutation (SNP) | VAF 56/243 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as COSV100144965, COSV100145110; called by muse, mutect2, varscan2
- KIR2DL3 | c.918G>C p.L306F | Missense Mutation (SNP) | VAF 60/364 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.728); catalogued as COSV100668081; called by muse, mutect2
- KLHL12 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV100766175; called by muse, mutect2, varscan2
- KLK6 | c.422T>A p.L141Q | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV100037841; called by muse, mutect2, varscan2
- KMT2A | c.433G>T p.D145Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV100629781; called by muse, mutect2, varscan2
- KMT2B | c.3469G>T p.G1157C | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99720589; called by muse, mutect2, varscan2
- KMT2D | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.158); catalogued as COSV99985549; called by muse, mutect2, varscan2
- KPNA1 | c.1226C>T p.S409F | Missense Mutation (SNP) | VAF 10/211 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1403589287, COSV100724382; called by muse, mutect2
- KRT84 | c.1422C>A p.S474R | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.178); catalogued as COSV99231035; called by muse, mutect2, varscan2
- KRTAP10-8 | c.517C>A p.P173T | Missense Mutation (SNP) | VAF 135/348 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100555392; called by muse, mutect2, varscan2
- KRTAP19-1 | c.25G>C p.G9R | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.163); catalogued as COSV101185866, COSV66861691; called by muse, mutect2, varscan2
- KRTAP21-1 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 89/185 reads (48%) | SIFT tolerated, low confidence (0.42); PolyPhen probably damaging (0.993); catalogued as COSV100624963; called by muse, mutect2, varscan2
- KRTAP21-1 | c.109G>T p.G37W | Missense Mutation (SNP) | VAF 87/183 reads (48%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.999); catalogued as COSV100624886, COSV100624964; called by muse, mutect2, varscan2
- KTI12 | c.50G>C p.R17P | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100860258; called by muse, mutect2, varscan2
- L3MBTL3 | c.326A>T p.K109M | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.798); catalogued as COSV100696390; called by muse, mutect2, varscan2
- LAMB1 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99741624; called by muse, mutect2, varscan2
- LAMB4 | c.4639G>C p.D1547H | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as COSV99225505; called by muse, mutect2, varscan2
- LAMC1 | c.2206G>C p.E736Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.678); catalogued as COSV99280393; called by muse, mutect2, varscan2
- LAS1L | c.1469A>G p.Q490R | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV100408681; called by muse, mutect2, varscan2
- LCLAT1 | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 56/234 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100093170; called by muse, mutect2, varscan2
- LCN15 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.068); catalogued as rs755731638, COSV100293616; called by muse, mutect2, varscan2
- LEPR | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100756737; called by muse, mutect2
- LGSN | c.1481A>G p.N494S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV101040718; called by muse, mutect2, varscan2
- LPA | c.4232C>G p.S1411C | Missense Mutation (SNP) | VAF 48/301 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV100307992; called by muse, mutect2, varscan2
- LPCAT2 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100045304; called by muse, mutect2, varscan2
- LRIF1 | c.464C>G p.S155* | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | catalogued as COSV100870921; called by muse, mutect2, varscan2
- LRP1 | c.11853C>G p.H3951Q | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.031); catalogued as COSV99677137; called by muse, mutect2, varscan2
- LRP4 | c.4967C>T p.P1656L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.297); catalogued as rs1565777683, COSV101066860; called by muse, mutect2, varscan2
- LRRC34 | c.1349C>T p.S450L (on ENST00000446859 / NM_001172779.2; = p.S418L on NM_153353.5) | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.31); catalogued as COSV57186350; called by muse, mutect2, varscan2
- LSM14A | c.512G>T p.R171I | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.962); catalogued as COSV101471755; called by muse, mutect2, varscan2
- LUZP2 | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV100421285; called by muse, mutect2, varscan2
- LZTR1 | c.1265C>T p.S422F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99302273; called by muse, mutect2, varscan2
- MACROD2 | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99442174; called by muse, mutect2, varscan2
- MAGEL2 | c.3424G>C p.D1142H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.16); catalogued as COSV100046201; called by muse, mutect2, varscan2
- MAGEL2 | c.3308C>T p.S1103F | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.471); catalogued as rs1273877197, COSV58568522; called by muse, mutect2, varscan2
- MAIP1 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99705331; called by muse, mutect2, varscan2
- MAMLD1 | c.1917G>T p.Q639H | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1557406572, COSV99476556; called by muse, mutect2, varscan2
- MAN2A1 | c.3266C>G p.S1089C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.275); catalogued as COSV99811853; called by mutect2, varscan2
- MAP11 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.109); catalogued as rs893843642, COSV100385633; called by mutect2, varscan2
- MAP2 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV99561608; called by muse, mutect2, varscan2
- MAP3K1 | c.1099C>T p.Q367* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV68122464; called by muse, mutect2, varscan2
- MAP3K6 | c.3280C>T p.R1094C | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs755281486, COSV100539591; called by muse, mutect2, varscan2
- MAP4K1 | c.687G>C p.K229N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101204390; called by muse, mutect2, varscan2
- MAP4K1 | c.537G>A p.M179I | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV101204393; called by muse, mutect2
- MAPK12 | c.660C>G p.I220M | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV99299672; called by muse, mutect2, varscan2
- MAPK8 | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100827536; called by muse, mutect2, varscan2
- MAX | c.21C>G p.I7M | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.408); catalogued as rs760248675, COSV52419246, COSV99408642; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MBTPS1 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 14/124 reads (11%) | catalogued as rs34076105, COSV100597784; called by muse, mutect2, varscan2
- MCM2 | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 53/311 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.175); catalogued as COSV99413442; called by muse, mutect2, varscan2
- MCM8 | c.1734-1G>A p.X578_splice | Splice Site (SNP) | VAF 5/63 reads (8%) | catalogued as COSV99496223; called by muse, mutect2
- MCTS1 | c.38A>G p.N13S | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100989189; called by muse, mutect2
- ME2 | c.1003C>A p.Q335K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs944913092, COSV100360937; called by muse, mutect2, varscan2
- MED12 | c.4109C>A p.T1370N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as COSV100379820; called by muse, mutect2, varscan2
- MED12L | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.192); catalogued as COSV56400135; called by muse, mutect2
- MED8 | c.575C>G p.S192C | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs753451301, COSV99318499; called by muse, mutect2, varscan2
- MICALL2 | c.822G>T p.Q274H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.592); catalogued as COSV99876258; called by muse, mutect2
- MID2 | c.1071G>C p.E357D | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.061); catalogued as COSV99465548; called by muse, mutect2, varscan2
- MIER1 | c.277G>A p.E93K (on ENST00000355356 / NM_001077701.3; = p.E110K on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as COSV100591275, COSV100591315; called by muse, mutect2
- MIER1 | c.824G>T p.R275I (on ENST00000355356 / NM_001077701.3; = p.R292I on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV100591293, COSV62529204; called by muse, mutect2, varscan2
- MIOS | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.949); catalogued as rs1315484939, COSV100402947; called by muse, mutect2, varscan2
- MMP7 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.593); catalogued as rs1244583716, COSV52772892; called by muse, mutect2, varscan2
- MMUT | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.04); catalogued as COSV99222553; called by muse, mutect2, varscan2
- MNS1 | c.121C>G p.Q41E | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as COSV99549812; called by muse, mutect2, varscan2
- MOCOS | c.2343C>G p.I781M | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV99733894; called by muse, mutect2
- MON2 | c.3467G>T p.S1156I | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99743547; called by muse, mutect2, varscan2
- MPND | c.918G>C p.Q306H | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.426); catalogued as COSV99515345; called by muse, mutect2, varscan2
- MROH7 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.986); catalogued as COSV100273816, COSV100274002; called by muse, mutect2, varscan2
- MROH7 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.271); catalogued as rs1336600740, COSV100274012; called by muse, mutect2, varscan2
- MROH7 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.996); catalogued as COSV100274013; called by muse, mutect2, varscan2
- MRPL22 | c.382G>T p.V128L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.547); catalogued as COSV54557915, COSV99501804; called by muse, mutect2, varscan2
- MRPL53 | c.90G>A p.T30= | Splice Region (SNP) | VAF 28/130 reads (22%) | catalogued as COSV50688630, COSV99252249; called by muse, mutect2, varscan2
- MSMP | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.371); catalogued as COSV100960353; called by muse, mutect2, varscan2
- MTG2 | c.792del p.I265Sfs*10 | Frame Shift Del (DEL) | VAF 15/52 reads (29%) | catalogued as COSV63693911, COSV63694596; called by mutect2, pindel, varscan2
- MTM1 | c.758G>T p.R253L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100080665, COSV60333518; called by muse, mutect2, varscan2
- MTREX | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100044498; called by muse, mutect2, varscan2
- MUC16 | c.40661G>T p.R13554L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.976); catalogued as rs548751371, COSV101109391; called by muse, mutect2, varscan2
- MUC16 | c.7748C>A p.S2583Y | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV101201491; called by muse, mutect2
- MUC3A | c.8660C>G p.S2887C | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.353); catalogued as COSV100115343; called by muse, mutect2
- MUS81 | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100337224; called by muse, mutect2, varscan2
- MX2 | c.805G>C p.D269H | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100416175; called by muse, mutect2, varscan2
- MYADM | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1174657142, COSV100425197; called by muse, mutect2, varscan2
- MYBPC2 | c.2397G>C p.K799N | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV100732017; called by muse, mutect2
- MYH13 | c.2740A>T p.K914* | Nonsense Mutation (SNP) | VAF 13/26 reads (50%) | catalogued as COSV99355384; called by muse, mutect2, varscan2
- MYH13 | c.391T>A p.W131R | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV52835070; called by muse, varscan2
- MYL12A | c.367A>G p.R123G | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV54182935, COSV99470257; called by muse, mutect2
- MYO16 | c.1057A>C p.K353Q | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99194572; called by muse, mutect2, varscan2
- MYO1E | c.2062G>T p.E688* | Nonsense Mutation (SNP) | VAF 11/113 reads (10%) | catalogued as COSV99896578; called by muse, mutect2
- MYO1G | c.2420C>T p.S807L | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.231); catalogued as COSV99349103; called by muse, mutect2, varscan2
- MYO5A | c.2180G>T p.C727F | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100698135; called by muse, mutect2, varscan2
- MYO9B | c.3166G>C p.E1056Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV101261916, COSV68283203; called by muse, mutect2
- NAA20 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV100131827; called by muse, mutect2
- NAP1L3 | c.988C>T p.Q330* | Nonsense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as COSV100220656; called by muse, mutect2, varscan2
- NAPEPLD | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs1369263175, COSV100440041; called by muse, mutect2, varscan2
- NBEAL1 | c.7421G>A p.G2474E | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101355613; called by muse, mutect2, varscan2
- NBPF9 | c.1507G>C p.E503Q | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99914606; called by muse, mutect2, varscan2
- NCAPD3 | c.3313G>C p.E1105Q | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.422); catalogued as COSV101594458; called by muse, mutect2
- NCAPG | c.2227G>C p.E743Q | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99266172; called by muse, mutect2, varscan2
- NCOA6 | c.1157C>G p.A386G | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as COSV100750332; called by muse, mutect2, varscan2
- NDC1 | c.1859G>T p.G620V | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.771); catalogued as COSV99323937; called by muse, mutect2, varscan2
- NDUFS4 | c.436G>C p.D146H | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.905); catalogued as COSV99692425; called by muse, mutect2, varscan2
- NEB | c.15109G>T p.D5037Y | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99427694; called by muse, mutect2, varscan2
- NECTIN4 | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as COSV100920035; called by muse, mutect2, varscan2
- NFKB1 | c.2408T>C p.L803P (on ENST00000394820 / NM_001382627.1; = p.L804P on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV99897846; called by muse, mutect2, varscan2
- NFX1 | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100582443; called by muse, mutect2, varscan2
- NFYB | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99527104; called by muse, mutect2
- NHS | c.2507C>T p.S836L | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101196955; called by muse, mutect2, varscan2
- NID1 | c.550G>C p.A184P | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99938275; called by muse, mutect2
- NINL | c.3351G>A p.Q1117= | Splice Region (SNP) | VAF 6/65 reads (9%) | catalogued as COSV99626253; called by muse, mutect2, varscan2
- NIPBL | c.1750G>T p.D584Y | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as COSV99242537; called by muse, mutect2, varscan2
- NISCH | c.877G>T p.D293Y | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100617669; called by muse, mutect2, varscan2
- NLRP3 | c.821T>C p.I274T | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100275789, COSV100276615; called by muse, mutect2, varscan2
- NLRP6 | c.1876T>C p.Y626H | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV100381159; called by muse, varscan2
- NLRP7 | c.516C>A p.Y172* | Nonsense Mutation (SNP) | VAF 22/86 reads (26%) | catalogued as COSV100053341; called by muse, mutect2, varscan2
- NLRX1 | c.2312G>A p.R771Q | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.96); catalogued as rs774796960, COSV99424867; called by muse, mutect2, varscan2
- NOL11 | c.1630G>C p.E544Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.092); catalogued as COSV99475268; called by muse, mutect2, varscan2
- NOL11 | c.1819G>C p.D607H | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV99475270; called by muse, mutect2, varscan2
- NOS2 | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 24/114 reads (21%) | catalogued as COSV100569883; called by muse, mutect2, varscan2
- NPAS2 | c.2121G>C p.Q707H | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as COSV100176911; called by muse, mutect2, varscan2
- NPAS4 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 38/295 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100215245; called by muse, mutect2, varscan2
- NPAS4 | c.2077G>A p.E693K | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV60651973; called by muse, mutect2, varscan2
- NPHP3 | c.1983G>A p.W661* | Nonsense Mutation (SNP) | VAF 4/54 reads (7%) | catalogued as COSV100447339; called by muse, mutect2
- NPHS1 | c.2306T>A p.L769H | Missense Mutation (SNP) | VAF 51/225 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV100800250; called by muse, mutect2, varscan2
- NR1H4 | c.925G>T p.V309L (on ENST00000551379 / NM_001206993.2; = p.V295L on NM_005123.4) | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.162); catalogued as COSV99501164; called by muse, mutect2, varscan2
- NR5A2 | c.404G>A p.R135K (on ENST00000367362 / NM_205860.3; = p.R89K on NM_003822.5) | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52646936, COSV99371661; called by muse, mutect2
- NTM | c.91G>T p.V31L | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100869468, COSV100869668; called by muse, mutect2, varscan2
- NTM | c.467C>A p.T156N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.449); catalogued as COSV100869471; called by muse, mutect2, varscan2
- NUBP2 | c.136-2A>T p.X46_splice | Splice Site (SNP) | VAF 16/34 reads (47%) | catalogued as COSV99236687; called by muse, mutect2, varscan2
- NUDT12 | c.220A>C p.I74L | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100048346; called by muse, mutect2, varscan2
- NUMB | c.831C>G p.F277L (on ENST00000355058; = p.F266L on NM_003744.5) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.921); catalogued as COSV100680019; called by muse, mutect2, varscan2
- NUP205 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | catalogued as COSV53664415; called by muse, mutect2
- NUP210L | c.2347C>A p.H783N | Missense Mutation (SNP) | VAF 100/362 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as COSV99669046; called by muse, mutect2, varscan2
- NUP58 | c.206G>C p.G69A | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV67751500; called by muse, mutect2, varscan2
- NUTM1 | c.955C>G p.L319V | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV100412590; called by muse, mutect2, varscan2
- OASL | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV99984648; called by muse, mutect2, varscan2
- OBSCN | c.7195G>C p.E2399Q | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.86); catalogued as COSV99484003; called by muse, mutect2, varscan2
- OFD1 | c.2231G>C p.R744T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100407131; called by muse, mutect2, varscan2
- OMD | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1160180887, COSV100979086; called by muse, mutect2
- OPN3 | c.1016C>G p.P339R | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV100087835; called by muse, mutect2, varscan2
- OR10A2 | c.161C>A p.S54Y | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV100225174; called by muse, mutect2, varscan2
- OR10R2 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 63/334 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1352239072, COSV63768728; called by muse, mutect2, varscan2
- OR10T2 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs772691278, COSV57783296, COSV57784051; called by muse, mutect2, varscan2
- OR13G1 | c.328G>T p.V110F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs776565972, COSV62944463; called by muse, mutect2, varscan2
- OR1A1 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as rs267604805, COSV100410830, COSV58403914; called by muse, mutect2, varscan2
- OR1C1 | c.705G>C p.Q235H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as COSV68716349, COSV68716584; called by muse, mutect2, varscan2
- OR2J2 | c.416C>A p.P139H | Missense Mutation (SNP) | VAF 79/365 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV101013462; called by muse, mutect2
- OR2L2 | c.160C>A p.L54I | Missense Mutation (SNP) | VAF 83/377 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63548275; called by muse, mutect2, varscan2
- OR4C12 | c.488G>T p.W163L | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.222); catalogued as COSV100078674; called by muse, mutect2, varscan2
- OR4K13 | c.205A>G p.I69V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as COSV100237883; called by muse, mutect2, varscan2
- OR4X2 | c.870G>T p.M290I | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100183337; called by muse, mutect2, varscan2
- OR51E2 | c.388C>A p.R130S | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs757545384, COSV101211322, COSV101211398; called by muse, mutect2, varscan2
- OR52B2 | c.88T>C p.S30P | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV101603964; called by muse, mutect2, varscan2
- OR5K1 | c.143T>G p.L48R | Missense Mutation (SNP) | VAF 81/286 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100221027; called by muse, mutect2, varscan2
- OR5T1 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV100479223; called by muse, mutect2, varscan2
- OR5W2 | c.766C>G p.L256V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.302); catalogued as COSV100747744; called by muse, mutect2, varscan2
- OR6K6 | c.320C>G p.P107R (on ENST00000368144; = p.P83R on NM_001005184.1) | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100933791; called by muse, mutect2, varscan2
- OR6Q1 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as rs756281064, COSV100110505; called by muse, mutect2, varscan2
- OR8H2 | c.326C>A p.T109N | Missense Mutation (SNP) | VAF 70/327 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV57943503; called by muse, mutect2, varscan2
- OR8K3 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV100449771; called by muse, mutect2, varscan2
- P2RY4 | c.17C>A p.S6Y | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV100997052; called by muse, mutect2, varscan2
- PABPC5 | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100442666; called by muse, mutect2, varscan2
- PAF1 | c.1264G>T p.E422* | Nonsense Mutation (SNP) | VAF 34/402 reads (8%) | catalogued as COSV99656018; called by muse, mutect2
- PAGR1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.374); catalogued as COSV100232790; called by muse, mutect2
- PALMD | c.1567G>C p.D523H | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99586658; called by muse, mutect2, varscan2
- PAPPA2 | c.1150C>T p.Q384* | Nonsense Mutation (SNP) | VAF 19/94 reads (20%) | catalogued as COSV100867126; called by muse, mutect2, varscan2
- PARP8 | c.2434G>T p.D812Y | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99892730; called by muse, mutect2, varscan2
- PCARE | c.3218C>A p.P1073H | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100527857; called by muse, mutect2, varscan2
- PCARE | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.242); catalogued as COSV100527858; called by muse, mutect2, varscan2
- PCDHB11 | c.1585T>A p.F529I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV100697166; called by muse, mutect2, varscan2
- PCDHGA5 | c.1417T>G p.S473A | Missense Mutation (SNP) | VAF 66/135 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.119); catalogued as COSV99546371; called by muse, mutect2, varscan2
- PDE8B | c.517C>G p.L173V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.909); catalogued as COSV53732551, COSV99367542; called by muse, mutect2, varscan2
- PDIA3 | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as rs755677588, COSV100295288; called by mutect2, varscan2
- PHKA2 | c.3699G>T p.Q1233H | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.285); catalogued as COSV101177433; called by muse, mutect2, varscan2
- PIGN | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1483184135, COSV100716185; called by muse, mutect2
- PIK3AP1 | c.23G>A p.R8K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as COSV100225525; called by muse, mutect2, varscan2
- PIK3C2A | c.1672C>G p.H558D | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV99791184; called by muse, mutect2, varscan2
- PIK3CB | c.1618G>C p.E540Q | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.173); catalogued as COSV100006086, COSV56683304, COSV56689052; called by muse, mutect2, varscan2
- PIK3CB | c.1187G>C p.R396T | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100006089; called by muse, mutect2, varscan2
- PIP5K1B | c.289C>A p.L97I | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as COSV99599726; called by muse, mutect2, varscan2
- PJA2 | c.85C>G p.Q29E | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as COSV100754534; called by muse, mutect2, varscan2
- PKD1L1 | c.1715C>T p.S572F | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99221302; called by muse, mutect2
- PKHD1 | c.7884G>C p.E2628D | Missense Mutation (SNP) | VAF 17/194 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as COSV100584495; called by muse, mutect2
- PKHD1L1 | c.1083C>A p.Y361* | Nonsense Mutation (SNP) | VAF 29/83 reads (35%) | catalogued as COSV101006794; called by muse, mutect2, varscan2
- PKHD1L1 | c.6451C>G p.L2151V | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV101006795; called by muse, mutect2, varscan2
- PLA2G2E | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0.091); catalogued as rs775498456, COSV100908835, COSV64290450; called by muse, mutect2, varscan2
- PLCB1 | c.1965G>A p.M655I | Missense Mutation (SNP) | VAF 24/359 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV62057765; called by muse, mutect2
- PLCH1 | c.1360G>A p.A454T (on ENST00000340059 / NM_001130960.2; = p.A466T on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 151/340 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100398167; called by muse, mutect2, varscan2
- PLEKHM2 | c.2297C>T p.S766L | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs1484744601, COSV101009200; called by muse, mutect2
- PLEKHM3 | c.1333C>G p.Q445E | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV101216857; called by muse, mutect2, varscan2
- PLEKHN1 | c.392C>G p.S131W | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs577334355, COSV100379289; called by muse, mutect2, varscan2
- PLS3 | c.1325G>A p.W442* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV99172124; called by muse, mutect2, varscan2
- PLXNB3 | c.2295C>G p.I765M | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs1333735113, COSV100737895; called by muse, mutect2, varscan2
- PMP2 | c.223A>G p.T75A | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs765430447, COSV99808325; called by muse, mutect2, varscan2
- PNLDC1 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV99277859; called by muse, mutect2
- PODXL2 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.021); catalogued as rs1449844076, COSV100686587; called by muse, mutect2, varscan2
- POLR1E | c.790C>G p.P264A (on ENST00000377792 / NM_001282766.1; = p.P202A on NM_022490.4) | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100905430; called by muse, mutect2
- POLR2F | c.122C>G p.S41C | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.375); catalogued as rs775564769, COSV101328974; called by muse, mutect2
- POLR2L | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV100431904; called by muse, mutect2, varscan2
- POM121L12 | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV68694321; called by muse, mutect2, varscan2
- PON3 | c.781A>G p.I261V | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.049); catalogued as COSV99672710; called by muse, mutect2, varscan2
- POP1 | c.692A>G p.H231R | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV100856101; called by muse, mutect2, varscan2
- PPDPFL | c.110T>C p.I37T | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV57460679; called by muse, mutect2, varscan2
- PPFIA3 | c.3352G>A p.E1118K | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs1233005037, COSV53257877; called by muse, mutect2, varscan2
- PPFIBP1 | c.31G>C p.A11P | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57297451, COSV99945391; called by muse, mutect2, varscan2
- PPIE | c.716C>G p.S239C | Missense Mutation (SNP) | VAF 16/237 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.299); catalogued as rs1440973128, COSV60973240; called by muse, mutect2
- PPP1R12A | c.2786C>T p.S929L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99700822; called by muse, mutect2
- PPP1R13B | c.1895C>T p.S632F | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.084); catalogued as COSV99162046; called by muse, mutect2
- PPP1R13B | c.1697C>T p.S566F | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.957); catalogued as COSV99162063; called by muse, mutect2, varscan2
- PPP6C | c.474G>C p.Q158H | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.511); catalogued as COSV101001250; called by muse, mutect2, varscan2
- PRB2 | c.1024C>G p.P342A | Missense Mutation (SNP) | VAF 31/240 reads (13%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.693); catalogued as COSV101231494, COSV101231496, COSV66983207; called by muse, mutect2, varscan2
- PRDM10 | c.1643A>C p.H548P | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV100457021; called by muse, mutect2, varscan2
- PRKCE | c.1897G>T p.E633* | Nonsense Mutation (SNP) | VAF 9/85 reads (11%) | catalogued as COSV100079384; called by muse, mutect2, varscan2
- PRMT3 | c.1243G>C p.E415Q | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs551794312, COSV100424210; called by muse, mutect2, varscan2
- PRR14 | c.1298C>T p.S433L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV99788617; called by muse, mutect2, varscan2
- PSMA8 | c.124A>G p.I42V | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV100379124; called by muse, mutect2, varscan2
- PTCD2 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as rs758600787, COSV54648618, COSV99782473; called by muse, varscan2
- PTCHD4 | c.846C>G p.I282M | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100261580; called by muse, mutect2, varscan2
- PTEN | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs587780004, COSV100911304, COSV64289791; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRR | c.1329G>C p.L443F | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV51731075; called by muse, mutect2, varscan2
- PTPRT | c.586C>G p.L196V | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV100630304; called by muse, mutect2, varscan2
- QRICH1 | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.112); catalogued as COSV100676969; called by muse, mutect2, varscan2
- RAB11FIP1 | c.447G>A p.M149I | Missense Mutation (SNP) | VAF 18/323 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99770458; called by muse, mutect2
- RAB3A | c.113T>C p.F38S | Missense Mutation (SNP) | VAF 69/270 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.609); catalogued as COSV99718113; called by muse, mutect2, varscan2
- RABEP2 | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 20/129 reads (16%) | catalogued as COSV100707212; called by muse, mutect2, varscan2
- RANBP17 | c.2092G>C p.E698Q | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.271); catalogued as COSV101206376; called by muse, mutect2, varscan2
- RANBP2 | c.4187C>T p.T1396I | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV99313200; called by muse, mutect2, varscan2
- RAPGEF1 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV64698935; called by muse, mutect2, varscan2
- RAPGEF5 | c.799G>A p.E267K (on ENST00000401957 / NM_001367602.2; = p.E570K on NM_012294.5) | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV100687835, COSV100687864; called by muse, mutect2
- RAVER2 | c.455C>G p.S152C | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV99605652; called by muse, mutect2, varscan2
- RBBP7 | c.544C>G p.L182V | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.68); catalogued as COSV101198324; called by muse, mutect2, varscan2
- RBFA | c.992G>A p.R331K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100080326, COSV51534376; called by muse, mutect2
- RBM39 | c.1222G>A p.E408K (on ENST00000253363 / NM_001323424.2; = p.E402K on NM_004902.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.138); catalogued as COSV99488888; called by muse, mutect2, varscan2
- RBSN | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs148400688; called by muse, mutect2, varscan2
- RC3H1 | c.2646C>G p.I882M | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99281635, COSV99281735; called by muse, mutect2, varscan2
- RCC2 | c.1105G>C p.D369H | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100965198; called by muse, varscan2
- RDM1 | c.722G>C p.R241T | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.142); catalogued as rs192386068; called by muse, mutect2, varscan2
- REV3L | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.445); catalogued as rs1231437092, COSV100725669; called by muse, mutect2, varscan2
- RFPL1 | c.256C>G p.Q86E | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.403); catalogued as COSV62978376; called by muse, mutect2, varscan2
- RGS12 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 23/137 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV100376339; called by muse, mutect2, varscan2
- RHCG | c.1100A>G p.Y367C | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99174244; called by muse, mutect2, varscan2
- RIN1 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.992); catalogued as COSV100254974; called by muse, mutect2, varscan2
- RIOK1 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV99344908; called by muse, mutect2, varscan2
- RLIM | c.731A>G p.H244R | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as COSV100223306; called by muse, mutect2, varscan2
- RNASEL | c.858G>T p.K286N | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as COSV100842643; called by muse, mutect2, varscan2
- RNF144B | c.55C>G p.P19A | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99465087; called by muse, mutect2
- RNF170 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 16/200 reads (8%) | catalogued as COSV99533893; called by muse, mutect2
- RNF217 | c.1174G>C p.E392Q (on ENST00000521654 / NM_001286398.2; = p.E100Q on NM_152553.5) | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.874); catalogued as COSV51577227, COSV99255340; called by muse, mutect2, varscan2
- ROCK2 | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.391); catalogued as COSV100255916; called by muse, mutect2, varscan2
- ROS1 | c.3791G>C p.R1264T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV63853187; called by muse, mutect2, varscan2
- RPAP1 | c.119G>A p.G40D | Missense Mutation (SNP) | VAF 85/294 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1419036829, COSV100427331; called by muse, mutect2, varscan2
- RPH3A | c.1524G>C p.Q508H (on ENST00000389385 / NM_001143854.2; = p.Q504H on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as rs1168985423, COSV101231889; called by muse, mutect2, varscan2
- RPIA | c.403-1G>T p.X135_splice | Splice Site (SNP) | VAF 21/88 reads (24%) | catalogued as COSV99376443; called by muse, mutect2, varscan2
- RPS6KA3 | c.1900G>T p.G634C | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1555926346, COSV101084653; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RRAGD | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 79/314 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100784645; called by muse, mutect2, varscan2
- RRP1B | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs145745406; called by muse, mutect2, varscan2
- RSF1 | c.3704A>C p.E1235A | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.525); catalogued as COSV100407903; called by muse, mutect2, varscan2
- RSPH6A | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 88/396 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV99680095; called by muse, mutect2, varscan2
- RTN4 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100463921; called by muse, mutect2, varscan2
- RUBCNL | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100529363; called by muse, varscan2
- RUSC1 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.077); catalogued as COSV99430253; called by muse, mutect2
- RXFP2 | c.1844C>G p.S615C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100034608, COSV53636174; called by muse, mutect2, varscan2
- RXRB | c.583C>G p.P195A | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV100807858, COSV63399874; called by muse, mutect2
- SAGE1 | c.2072C>G p.S691C | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as rs782511869, COSV100187869; called by muse, mutect2, varscan2
- SASS6 | c.118C>G p.H40D | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99791075; called by muse, mutect2, varscan2
- SC5D | c.682C>T p.H228Y | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.688); catalogued as COSV99873215; called by muse, varscan2
- SCGB2A2 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | catalogued as COSV99929280; called by muse, mutect2, varscan2
- SCN10A | c.5816C>G p.S1939* | Nonsense Mutation (SNP) | VAF 20/48 reads (42%) | catalogued as COSV101479528; called by muse, mutect2, varscan2
- SCN10A | c.4617G>C p.W1539C | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71862209; called by muse, mutect2
- SCN1A | c.3091T>A p.Y1031N (on ENST00000303395 / NM_001202435.3; = p.Y1020N on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100321974; called by muse, mutect2, varscan2
- SCN3A | c.3515-2A>T p.X1172_splice | Splice Site (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99328431; called by muse, mutect2
- SCN8A | c.4549G>A p.D1517N | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100634249; called by muse, mutect2, varscan2
- SCNN1A | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.428); catalogued as rs866470382, COSV99964935; called by muse, mutect2
- SCRT1 | c.939C>G p.F313L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59782145; called by muse, mutect2
- SDC2 | c.513G>C p.M171I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100143987; called by muse, mutect2, varscan2
- SDHAF2 | c.14C>T p.T5I | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.007); catalogued as COSV100074040; called by muse, mutect2, varscan2
- SDK1 | c.5941G>A p.V1981M | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV101269808; called by muse, mutect2, varscan2
- SEC24A | c.1712C>T p.S571L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.588); catalogued as COSV59750249; called by muse, mutect2, varscan2
- SELENOO | c.1981G>A p.A661T | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as rs1461535085, COSV99956275; called by muse, mutect2
- SEMA4A | c.2158G>C p.E720Q | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV100740732; called by muse, mutect2
- SEMA4C | c.1949C>T p.S650L | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.077); catalogued as rs766585970, COSV59691204; called by muse, mutect2, varscan2
- SEMG2 | c.554G>C p.R185T | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV101034232; called by muse, mutect2, varscan2
- SENP7 | c.652C>T p.H218Y | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.188); catalogued as rs184548923, COSV100053857; called by muse, mutect2, varscan2
- SEPTIN14 | c.680C>A p.T227K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV101193430; called by muse, mutect2, varscan2
- SEPTIN3 | c.166A>G p.M56V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.761); catalogued as rs886854169, COSV99352380; called by muse, mutect2, varscan2
- SERPINA5 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.18); catalogued as COSV100291810, COSV61574456; called by muse, mutect2
- SERPINB9 | c.705C>A p.D235E | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV101046729; called by muse, mutect2, varscan2
- SEZ6L | c.2062G>C p.E688Q | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.606); catalogued as COSV50660109, COSV99962860; called by muse, mutect2
- SF3B1 | c.3055A>G p.R1019G | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100135722; called by muse, mutect2
- SF3B3 | c.3079G>A p.D1027N | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100210213; called by muse, mutect2, varscan2
- SFN | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 22/88 reads (25%) | catalogued as COSV100212875; called by muse, mutect2, varscan2
- SFTPB | c.757T>A p.Y253N | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100667299, COSV60893021; called by muse, mutect2, varscan2
- SGCE | c.1115C>A p.A372D (on ENST00000647096; = p.A336D on NM_003919.3) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV99722908; called by muse, mutect2, varscan2
- SGIP1 | c.1517C>A p.T506N | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99392840; called by muse, mutect2, varscan2
- SGPP2 | c.1033C>G p.L345V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.043); catalogued as rs1450558556, COSV100346876, COSV58328849; called by muse, mutect2, varscan2
- SGSM1 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 5/49 reads (10%) | catalogued as COSV101240745; called by muse, mutect2, varscan2
- SGSM1 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.439); catalogued as rs748312188, COSV68509865; called by muse, mutect2, varscan2
- SH3GL2 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.075); catalogued as rs781631698, COSV66048228; called by muse, mutect2, varscan2
- SHCBP1L | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100772539; called by muse, mutect2, varscan2
- SHISA4 | c.85G>C p.E29Q | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as rs780009350, COSV100748258; called by muse, mutect2, varscan2
- SHTN1 | c.1012G>T p.V338F | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99599427; called by muse, mutect2, varscan2
- SIGLEC12 | c.637C>A p.Q213K (on ENST00000291707 / NM_053003.4; = p.Q95K on NM_033329.2) | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.456); catalogued as COSV99389592; called by muse, mutect2, varscan2
- SIGLEC8 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs200891335, COSV100367463; called by muse, mutect2, varscan2
- SIN3A | c.3810C>G p.F1270L | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.007); catalogued as COSV99145808; called by muse, mutect2, varscan2
- SIN3A | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1173797523, COSV64582255; called by muse, mutect2
- SLC12A4 | c.1541C>G p.S514* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100312219; called by muse, mutect2, varscan2
- SLC23A3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV99841360; called by muse, mutect2, varscan2
- SLC27A1 | c.1469C>G p.S490* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV53095953; called by muse, mutect2, varscan2
- SLC34A3 | c.11C>G p.S4C | Missense Mutation (SNP) | VAF 60/298 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV100746714; called by muse, mutect2, varscan2
- SLC35F5 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.051); catalogued as COSV99830262; called by muse, mutect2
- SLC36A3 | c.568C>G p.R190G | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100077721, COSV100077870, COSV58857616; called by muse, mutect2, varscan2
- SLC39A10 | c.2365G>A p.D789N | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as COSV100417437; called by muse, mutect2, varscan2
- SLC3A1 | c.1284C>G p.I428M | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs761578780, COSV99577628; called by muse, mutect2, varscan2
- SLC5A2 | c.1544C>T p.S515L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57890801; called by muse, mutect2, varscan2
- SLC6A3 | c.451T>A p.Y151N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99548819; called by muse, mutect2, varscan2
- SLC7A14 | c.402C>G p.F134L | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.621); catalogued as COSV51577748, COSV99200942; called by mutect2, varscan2
- SLCO1B3 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99682200; called by muse, mutect2
- SLITRK1 | c.1637G>A p.R546H | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV101000055; called by muse, mutect2, varscan2
- SLMAP | c.1525C>T p.H509Y (on ENST00000428312 / NM_001377924.1; = p.H571Y on NM_007159.5) | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.206); catalogued as COSV99909227; called by muse, mutect2, varscan2
- SMCHD1 | c.1884A>G p.I628M | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV99862529; called by muse, mutect2, varscan2
- SMCO1 | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.104); catalogued as COSV58839752; called by muse, mutect2
- SMG7 | c.1726G>C p.G576R | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.706); catalogued as COSV100750557; called by muse, mutect2, varscan2
- SMPD2 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV99238159; called by muse, mutect2, varscan2
- SMYD4 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as COSV100563228; called by muse, mutect2
- SNRNP40 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV99745686; called by muse, mutect2, varscan2
- SOCS6 | c.1526G>C p.R509P | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV101205858, COSV67546396; called by muse, mutect2, varscan2
- SORL1 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV99495391; called by muse, mutect2
- SPAG16 | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100535464; called by muse, mutect2, varscan2
- SPAM1 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99773440; called by muse, mutect2, varscan2
- SPART | c.1617G>A p.M539I | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.208); catalogued as COSV100768854; called by muse, mutect2, varscan2
- SPEF2 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99214817; called by muse, mutect2, varscan2
- SPEG | c.2801G>A p.R934H | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.139); catalogued as rs1327464996, COSV100405587; called by muse, mutect2
- SPG11 | c.4972C>T p.H1658Y | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.108); catalogued as rs775877332, COSV99969573; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPRY2 | c.887C>G p.S296* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV101001743, COSV65701529; called by muse, mutect2, varscan2
- SPTB | c.1883G>T p.G628V | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.216); catalogued as COSV101072403; called by muse, mutect2, varscan2
- SRCAP | c.8428G>A p.E2810K | Missense Mutation (SNP) | VAF 13/224 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV99351261; called by muse, mutect2
- SRD5A2 | c.25C>G p.P9A | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.297); catalogued as COSV99252603; called by muse, mutect2, varscan2
- SRGAP1 | c.17G>C p.R6P | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV100755112; called by muse, mutect2
- SRRT | c.1966C>T p.H656Y | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0.103); catalogued as rs1260282178, COSV99574541; called by muse, mutect2, varscan2
- SRSF11 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.422); catalogued as COSV100918013; called by muse, mutect2, varscan2
- SSH2 | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99282972; called by muse, mutect2, varscan2
- ST6GAL2 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 24/143 reads (17%) | PolyPhen benign (0.058); catalogued as COSV100868271; called by muse, mutect2, varscan2
- STAB2 | c.4042T>C p.C1348R | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101186276; called by muse, mutect2
- STARD7 | c.787A>T p.R263W | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100474906; called by muse, mutect2, varscan2
- STARD8 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as COSV99367605; called by muse, mutect2
- STAT2 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs755099508, COSV58476976; called by muse, mutect2, varscan2
- STK32C | c.504G>T p.M168I | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); catalogued as COSV100063409; called by muse, mutect2
- STRIP2 | c.519C>G p.H173Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.243); catalogued as COSV99974146; called by muse, mutect2, varscan2
- STYXL2 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.194); catalogued as COSV99609850; called by muse, mutect2, varscan2
- SYDE2 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.212); catalogued as COSV99320641; called by muse, mutect2
- SYNE1 | c.13079C>T p.A4360V (on ENST00000367255 / NM_182961.4; = p.A4289V on NM_033071.3) | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.316); catalogued as COSV99572939; called by muse, mutect2, varscan2
- TAGLN | c.386C>T p.T129I | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99639210; called by muse, mutect2, varscan2
- TANC1 | c.236C>G p.S79* | Nonsense Mutation (SNP) | VAF 18/187 reads (10%) | catalogued as rs776193769, COSV99715121; called by muse, mutect2, varscan2
- TASOR2 | c.6203C>A p.S2068Y | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.174); catalogued as COSV100050992, COSV60168236; called by muse, mutect2, varscan2
- TBC1D8B | c.715C>A p.Q239K | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV99345037; called by muse, mutect2, varscan2
- TBX15 | c.862-1G>A p.X288_splice (on ENST00000369429 / NM_001330677.2; = p.X182_splice on NM_152380.3) | Splice Site (SNP) | VAF 5/52 reads (10%) | catalogued as COSV52868926, COSV52868958; called by muse, mutect2
- TBX22 | c.953G>T p.G318V | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as COSV100960946, COSV64785782; called by muse, mutect2, varscan2
- TBX4 | c.187-1G>A p.X63_splice | Splice Site (SNP) | VAF 11/48 reads (23%) | catalogued as COSV99540665; called by muse, mutect2, varscan2
- TCEAL4 | c.641A>G p.Y214C | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV101010305; called by muse, mutect2, varscan2
- TCHH | c.2641G>C p.E881Q | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.323); catalogued as COSV64277210; called by muse, mutect2, varscan2
- TCN2 | c.57G>C p.E19D | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV99308797; called by muse, mutect2, varscan2
- TDRD5 | c.2140G>C p.E714Q | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV99676552, COSV99677105; called by muse, mutect2, varscan2
- TENT5A | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs1235572002, COSV100199161; called by muse, mutect2, varscan2
- THSD1 | c.787C>G p.P263A | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV99319067; called by muse, mutect2, varscan2
- TIGD7 | c.278C>G p.S93* | Nonsense Mutation (SNP) | VAF 6/69 reads (9%) | catalogued as COSV99240003; called by muse, mutect2
- TLCD4 | c.210C>G p.F70L | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100930788; called by muse, mutect2
- TMEM156 | c.327G>C p.M109I | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV100756103; called by muse, mutect2
- TMEM203 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100411273; called by muse, mutect2
- TMEM215 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.031); catalogued as COSV100713253; called by muse, mutect2, varscan2
- TNF | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV101403260; called by muse, mutect2, varscan2
- TNXB | c.9343G>A p.E3115K (on ENST00000647633; = p.E2868K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.557); catalogued as rs764870462, COSV100926401; called by muse, mutect2, varscan2
- TOPBP1 | c.4273G>C p.G1425R | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.981); catalogued as COSV99605804; called by muse, mutect2
- TP53 | c.192del p.R65Efs*58 | Frame Shift Del (DEL) | VAF 56/157 reads (36%) | catalogued as CD065798; called by mutect2, pindel, varscan2
- TRIM32 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV100528460; called by muse, mutect2, varscan2
- TRIM36 | c.1078G>C p.D360H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99142619; called by muse, mutect2, varscan2
- TRIM38 | c.1377T>A p.F459L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); catalogued as COSV100837640; called by muse, mutect2, varscan2
- TRIOBP | c.3086C>A p.P1029H | Missense Mutation (SNP) | VAF 85/277 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100731109; called by muse, mutect2, varscan2
- TRIP13 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs369447610; called by muse, mutect2
- TRMT9B | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1299684231, COSV71600407; called by muse, mutect2, varscan2
- TRNT1 | c.523G>C p.D175H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99285919; called by muse, mutect2, varscan2
- TRO | c.3080C>A p.A1027D | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV99436866, COSV99437268; called by muse, mutect2, varscan2
- TRPC4AP | c.949A>T p.S317C | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV99328874; called by muse, mutect2, varscan2
- TRPC5 | c.2453C>G p.P818R | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.023); catalogued as COSV53302368, COSV99462636; called by muse, mutect2, varscan2
- TRPM2 | c.1416C>G p.I472M | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100309289; called by muse, mutect2, varscan2
- TSGA10 | c.2071G>T p.E691* | Nonsense Mutation (SNP) | VAF 26/66 reads (39%) | catalogued as COSV100747789; called by muse, mutect2
- TSHR | c.2267C>T p.S756L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.05); catalogued as COSV99992792; called by muse, mutect2, varscan2
- TSPOAP1 | c.5045A>G p.Y1682C | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99272632; called by muse, mutect2, varscan2
- TTC13 | c.1716G>C p.W572C | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100793018; called by muse, mutect2, varscan2
- TTK | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV100036588; called by muse, mutect2, varscan2
- TTLL7 | c.1325C>G p.S442* | Nonsense Mutation (SNP) | VAF 4/58 reads (7%) | catalogued as COSV99553189; called by muse, mutect2
- TTN | c.71428G>A p.E23810K (on ENST00000591111; = p.E16386K on NM_003319.4) | Missense Mutation (SNP) | VAF 19/97 reads (20%) | PolyPhen benign (0.254); catalogued as COSV100628849; called by muse, mutect2, varscan2
- TTN | c.69463G>A p.E23155K (on ENST00000591111; = p.E15731K on NM_003319.4) | Missense Mutation (SNP) | VAF 5/87 reads (6%) | PolyPhen benign (0.298); catalogued as COSV100628853; called by muse, mutect2
- TTN | c.69039G>C p.E23013D (on ENST00000591111; = p.E15589D on NM_003319.4) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | PolyPhen probably damaging (0.97); catalogued as COSV100628854; called by muse, mutect2
- TTN | c.59794G>A p.D19932N (on ENST00000591111; = p.D12508N on NM_003319.4) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | PolyPhen probably damaging (0.998); catalogued as COSV100628857; called by mutect2, varscan2
- TTN | c.48079G>T p.E16027* (on ENST00000591111; = p.E8603* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | catalogued as COSV100628869; called by muse, mutect2, varscan2
- TTN | c.22475G>T p.G7492V (on ENST00000591111; = p.G6565V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | PolyPhen probably damaging (0.99); catalogued as COSV100628873; called by muse, mutect2, varscan2
- TTN | c.13786G>A p.E4596K (on ENST00000591111; = p.E3669K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | PolyPhen benign (0.26); catalogued as COSV100628876; called by muse, mutect2
- TYW3 | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.62); catalogued as COSV100904908; called by muse, mutect2, varscan2
- UBA2 | c.1303G>C p.D435H | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.912); catalogued as COSV99875790; called by muse, mutect2, varscan2
- UBE2E3 | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs774720190, COSV101150604, COSV66585347; called by muse, mutect2, varscan2
- UBQLN3 | c.1907A>T p.Q636L | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100293956; called by muse, mutect2, varscan2
- UBR1 | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs756388965, COSV51932873, COSV99317828; called by muse, mutect2
- UBTF | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 9/56 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV100256122; called by muse, mutect2, varscan2
- UFL1 | c.1387C>T p.Q463* | Nonsense Mutation (SNP) | VAF 13/70 reads (19%) | catalogued as rs756214508, COSV100990144; called by muse, mutect2, varscan2
- UGP2 | c.1491G>C p.K497N | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as COSV99708702; called by muse, mutect2, varscan2
- UHRF1BP1L | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as rs201321249, COSV99692121; called by muse, mutect2, varscan2
- UIMC1 | c.1726C>T p.Q576* | Nonsense Mutation (SNP) | VAF 22/113 reads (19%) | catalogued as COSV101022215; called by muse, mutect2, varscan2
- UNC5B | c.842G>C p.G281A | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100101332; called by muse, mutect2, varscan2
- URGCP | c.1789G>A p.G597R (on ENST00000453200 / NM_001077663.3; = p.G588R on NM_017920.4) | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs17851647, COSV56246958; called by muse, mutect2, varscan2
- USP20 | c.1899C>G p.I633M | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100204742; called by muse, mutect2
- USP53 | c.2549C>A p.S850Y | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.34); catalogued as COSV99918035; called by muse, mutect2, varscan2
- USP9X | c.3787G>C p.E1263Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as COSV100200060; called by muse, mutect2
- VAV1 | c.2029G>T p.E677* | Nonsense Mutation (SNP) | VAF 18/108 reads (17%) | catalogued as COSV100409461; called by muse, mutect2, varscan2
- VPS13A | c.4447G>C p.D1483H | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.749); catalogued as COSV100653480; called by muse, mutect2, varscan2
- VPS13A | c.5101G>A p.E1701K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100653486; called by muse, mutect2, varscan2
- WDCP | c.571C>G p.L191V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99722214; called by muse, mutect2
- WDPCP | c.656G>A p.G219D | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99706770; called by muse, mutect2, varscan2
- WDR62 | c.2833C>G p.L945V | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.241); catalogued as COSV99544183; called by muse, mutect2, varscan2
- WDR77 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV99330968; called by muse, mutect2
- WEE1 | c.1032G>C p.L344F | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV100219822; called by muse, mutect2, varscan2
- WNK1 | c.1261C>G p.P421A | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100268535; called by muse, mutect2, varscan2
- WNK1 | c.6700C>T p.Q2234* (on ENST00000315939 / NM_018979.4; = p.Q1986* on NM_014823.3) | Nonsense Mutation (SNP) | VAF 40/209 reads (19%) | catalogued as COSV99942708; called by muse, mutect2, varscan2
- XKR7 | c.1593G>T p.K531N | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV101629300; called by muse, mutect2, varscan2
- XKR9 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 38/270 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.918); catalogued as rs1184062575, COSV101281975; called by muse, mutect2
- YBX3 | c.1053G>T p.E351D | Missense Mutation (SNP) | VAF 118/384 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as COSV99685295; called by muse, mutect2, varscan2
- YIF1A | c.849C>G p.I283M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.243); catalogued as COSV100268556; called by muse, mutect2, varscan2
- YY1AP1 | c.1474A>G p.M492V (on ENST00000295566 / NM_139118.2; = p.M435V on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.187); catalogued as COSV99804673; called by muse, varscan2
- YY1AP1 | c.1367C>G p.S456* (on ENST00000295566 / NM_139118.2; = p.S399* on NM_018253.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | catalogued as COSV55121189, COSV99804676; called by muse, varscan2
- YY1AP1 | c.927-3C>T | Splice Region (SNP) | VAF 11/61 reads (18%) | catalogued as COSV99804678; called by muse, mutect2, varscan2
325 further variants in this file (48 protein-altering or splice-affecting, 264 silent, 13 other) are not listed here.
